Somatic mutation profile of tumor specimen TCGA-32-2638-01A (aliquot TCGA-32-2638-01A-01D-1495-08) from TCGA case TCGA-32-2638, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.5 years (24,658 days).
Specimen TCGA-32-2638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e12479f8-f010-4c9e-b81e-bf461f82b25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2638-10A (Blood Derived Normal), aliquot TCGA-32-2638-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/923df8d2-fcdb-4596-9132-f72b2ff913aa

The open-access MAF lists 62 somatic variants for this specimen: 38 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 23, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54397767; called by muse, mutect2, varscan2
- AMPD1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs142123340; called by muse, mutect2, varscan2
- ANKRD40 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs148279576; called by muse, mutect2, varscan2
- CACNA2D1 | c.2563G>A p.D855N (on ENST00000356253 / NM_001366867.1; = p.D843N on NM_000722.4) | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV62387228; called by muse, mutect2
- CLEC12A | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV58562133; called by muse, mutect2, varscan2
- COIL | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV53595853, COSV53596030; called by muse, mutect2, varscan2
- DTNB | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as rs373229134; called by muse, mutect2, varscan2
- DUSP11 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV55595673; called by muse, mutect2, varscan2
- ELP1 | c.2411G>T p.S804I | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV65899019; called by muse, mutect2
- GLUD2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.75); catalogued as rs1337766978, COSV60151956; called by muse, mutect2, varscan2
- ITGA3 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs772329786, COSV50326867; called by muse, mutect2, varscan2
- ITGB7 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs748193418, COSV57239719; called by muse, mutect2, varscan2
- JCAD | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs201422216; called by muse, mutect2, varscan2
- MAP3K20 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs768503188, COSV64377923, COSV64379461; called by muse, mutect2
- MAP4K4 | c.2107C>T p.R703C (on ENST00000347699 / NM_001242559.2; = p.R618C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs369479508; called by muse, mutect2, varscan2
- MRTFA | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as COSV62935272; called by muse, mutect2, varscan2
- MTMR3 | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770843170, COSV60306527; called by muse, mutect2, varscan2
- MYO1B | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as rs932592834, COSV58435406; called by muse, mutect2, varscan2
- NPC1L1 | c.3082G>A p.G1028S | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs984503930, COSV56928378; called by muse, mutect2, varscan2
- OR51T1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs201004265; called by muse, mutect2, varscan2
- OR52H1 | c.900G>T p.Q300H (on ENST00000322653; = p.Q306H on NM_001005289.1) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1237808346, COSV59505974; called by muse, mutect2
- SEC16B | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV57628533; called by muse, mutect2, varscan2
- SETBP1 | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as COSV56330907; called by muse, mutect2, varscan2
- SIK3 | c.2354G>A p.R785K (on ENST00000445177 / NM_001366686.2; = p.R743K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV52620064; called by muse, mutect2, varscan2
- SLC14A1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs867037711, COSV58930944, COSV58932610; called by muse, mutect2, varscan2
- TENM3 | c.1043T>C p.F348S | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs753220175, COSV69314794; called by muse, mutect2, varscan2
- TFEC | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55404467; called by muse, mutect2, varscan2
- TM4SF1 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV59525338; called by muse, varscan2
- TMCO5A | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs193920912, COSV60465474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM22 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371728648; called by muse, mutect2, varscan2
- UNC79 | c.2818A>G p.T940A (on ENST00000393151 / NM_001346218.2; = p.T763A on NM_020818.5) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.078); catalogued as COSV56401261; called by muse, mutect2, varscan2
- VPS53 | c.1900C>T p.Q634* (on ENST00000571805 / NM_001366253.2; = p.Q605* on NM_018289.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV52134690; called by muse, varscan2
- EDC3 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRK | c.1108del p.V370* | Frame Shift Del (DEL) | VAF 46/154 reads (30%) | called by mutect2, pindel, varscan2
- NCAM1 | c.1482_1489dup p.Q497Pfs*83 (on ENST00000316851 / NM_181351.5; = p.Q487Pfs*83 on NM_000615.7) | Frame Shift Ins (INS) | VAF 26/102 reads (25%) | called by mutect2, varscan2
- UBE2U | c.677+2_677+5del p.X226_splice | Splice Site (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel
- XPO4 | c.2943del p.Y981* | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4317G>A p.P1439= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as rs756524839, COSV60628841, COSV60631929; called by muse, mutect2, varscan2
- ASH1L | c.3420C>G p.S1140= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV64211499; called by muse, mutect2, varscan2
- GRK7 | c.75C>T p.C25= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV53824446; called by muse, mutect2, varscan2
- GSDMB | c.852C>T p.L284= (on ENST00000418519 / NM_001165958.1; = p.L262= on NM_018530.2) | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs762338887, COSV58781932; called by muse, mutect2, varscan2
- KCNH5 | c.723G>A p.K241= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV59763377; called by muse, mutect2, varscan2
- KCTD12 | c.855C>T p.S285= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1488381206, COSV58524894; called by muse, mutect2, varscan2
- KRTAP5-9 | c.345T>C p.C115= | Silent (SNP) | VAF 78/232 reads (34%) | catalogued as COSV73200242; called by muse, mutect2, varscan2
- LRRC8E | c.2328G>T p.L776= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV60718836; called by muse, mutect2, varscan2
- MPEG1 | c.1656G>A p.P552= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs545638736, COSV57091166; called by muse, mutect2, varscan2
- MRPL1 | c.228C>T p.P76= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100213738, COSV59676173; called by muse, mutect2, varscan2
- MUC16 | c.15303A>T p.S5101= | Silent (SNP) | VAF 67/255 reads (26%) | catalogued as COSV67481303; called by muse, mutect2, varscan2
- MUC17 | c.6162G>A p.T2054= | Silent (SNP) | VAF 82/248 reads (33%) | catalogued as rs534149898, COSV100074569, COSV60297499; called by muse, mutect2, varscan2
- NAF1 | c.951T>C p.D317= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV56805304; called by muse, mutect2, varscan2
- NKAIN2 | c.366T>A p.P122= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV63678361; called by muse, mutect2, varscan2
- OBSCN | c.23178G>A p.P7726= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs748518642, COSV62992706; called by muse, mutect2, varscan2
- OTUD6A | c.852C>G p.L284= | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as COSV57974045; called by muse, mutect2, varscan2
- SERPINA9 | c.690C>T p.G230= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs756763583, COSV54076899; called by muse, mutect2, varscan2
- TBX20 | c.1257G>A p.P419= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1472539296, COSV68783634; called by muse, mutect2, varscan2
- TECTA | c.5556C>T p.N1852= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV50761809; called by muse, mutect2, varscan2
- TEF | c.645C>A p.P215= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV56748492; called by muse, mutect2, varscan2
- UNC5C | c.2721C>T p.S907= | Silent (SNP) | VAF 79/186 reads (42%) | catalogued as COSV71661340; called by muse, mutect2, varscan2
- USH2A | c.123G>A p.E41= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV56407748; called by muse, mutect2, varscan2
- ZP4 | c.1044G>C p.V348= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV63912948; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055757 C>T | 3'Flank (SNP) | VAF 37/93 reads (40%) | catalogued as rs751576128; called by muse, mutect2, varscan2
